Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAIA, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAIA-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; seminoma; diameter 3.0 cm; no angio-invasion; focal invasion of rete testis;
no invasion of tunica albuginea, epididymis and spermatic cord not present in the available
slides.

Date of procurement (= date of orchidectomy):

ICD O-3
Seminoma, NOS 9061/3
Site: O Testis NOS 062!
JW 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 4f3aa233-fb6d-4f68-82cc-872182f5cf78 (TCGA-2G-AAIA-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).